Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A5TU, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A5TU-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3

Astrocytoma, NOS 9400/3
Site C6CF Supratentorial NOS
C71.0
path Brain NOS C71.9
JW 4/18/13

Surgical Pathology Report

Patient Name: Phone #: Accession #:
Med. Rec. #: Client: Taken:
DOB: (Age: Location: Received:
Gender: F Accnt: Reported:
Physician(s):
Phy Location:

Clinical History

-year-old woman develops altered mental status, and on imaging has bifrontal, parasagittal abnormal signal with gyral expansion, 5.6 cm, minimal enhancement, and edema with mass effect.

Operative Diagnoses

Operation / Specimen

A: Brain tumor, biopsy

Pathologic Diagnosis

Brain, site not specified, biopsy: Astrocytoma (WHO 2).

IDH1-R132H: Positive.

MIB-1 proliferation index: 2%.

1p, 19q LOH (codeletion): Negative.

See Microscopy Description and Comment.

Comment

The sections contain small fragments of a glioma that diffusely infiltrates the cerebral cortex, and has some microcystic change. There are not mitotic figures. There is some endothelial hyperplasia, but not microvascular cellular proliferation or tumor necrosis. The features are those of a low histological grade glioma, with positive IDH 1, a low MIB-1 proliferation index of 2%, and a negative LOH (there is not codeletion of 1p, 19q), i.e. an astrocytoma, WHO grade 2.

Electronically Signed Out

Consultant:

Senior Staff Pathologist
Senior Staff Pathologist

Procedures/Addenda

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: Date Reported:

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Surgical Pathology

Page 2 of 3

Informative loci are: D1S552, D1S468, D1S1612, D1S496, D19S412, D19S606

Results-Comments

Testing performed on DNA extracted from tumor paraffin block
extracted from a corresponding
blood specimen was used as a normal reference control.

-A1. DNA

H and E stained sections were examined and no microdissection was needed to enrich tumor DNA.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3

markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and

[page 2 of 2]
D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

Electronically Signed Out

Senior Staff Pathologist

Intra-Operative Consultation

A.

Brain tumor, biopsy: Glioma, consistent with oligodendroglioma, other. Touch preparation smears performed at and results reported to the Physician of Record.

Staff Pathologist

Gross Description

A.

"Brain tumor", received fresh, three fragments, 0.6 cm in aggregate. Semi firm, greyish-pink. In total, A1.

Microscopic Description

IMMUNOHISTOCHEMISTRY: The CD163 demonstrates only quiescent perivascular microglia. The IDH1 is positive. With the MIB-1 there is a proliferation index of 2%.

Surgical Pathology

Page

Source: NCI Genomic Data Commons file 957a07b3-707a-47f2-8c92-1dc6eae6b612 (TCGA-DU-A5TU.6F62570D-D7DE-45F2-8025-49883C35BD82.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).